Somatic mutation profile of tumor specimen TCGA-ER-A2NH-06A (aliquot TCGA-ER-A2NH-06A-11D-A196-08) from TCGA case TCGA-ER-A2NH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.6 years (18,838 days).
Specimen TCGA-ER-A2NH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8131dab7-3065-4cf6-871a-6e7facb00909.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A2NH-10A (Blood Derived Normal), aliquot TCGA-ER-A2NH-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22e8528a-653c-4b16-922e-b761105f72d2

The open-access MAF lists 357 somatic variants for this specimen: 233 protein-altering or splice-affecting, 121 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 211, Silent 121, Nonsense Mutation 17, Intron 2, Splice Region 2, Splice Site 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1S | c.1269G>A p.W423* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as rs1558075630, COSV62937598; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 304/391 reads (78%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV62321888; called by muse, varscan2
- ACAN | c.5101G>A p.D1701N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV61357710; called by muse, mutect2, varscan2
- ACSM4 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV68066569; called by muse, mutect2, varscan2
- ACTR10 | c.1145G>C p.G382A | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV54297719; called by muse, mutect2, varscan2
- ADAM2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs781759811, COSV55860004; called by mutect2, varscan2
- ADAM23 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343752353, COSV100008254; called by muse, mutect2, varscan2
- ADAMTS16 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56982306; called by muse, mutect2, varscan2
- ADGRB3 | c.4061C>T p.P1354L | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV53238377; called by muse, mutect2, varscan2
- ADGRG4 | c.9238C>T p.P3080S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as COSV54951827; called by muse, mutect2, varscan2
- AFF4 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV54792773; called by muse, mutect2, varscan2
- AJAP1 | c.1079G>A p.C360Y | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65449586; called by mutect2, varscan2
- AMIGO2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.179); catalogued as COSV56973136, COSV56973624; called by muse, varscan2
- AMIGO2 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV56973578; called by muse, varscan2
- ANGPT1 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs757109289, COSV52434162; called by mutect2, varscan2
- APOL6 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV68749410; called by muse, mutect2, varscan2
- ASPM | c.8360T>C p.V2787A | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.171); catalogued as rs111685217, COSV54126638; called by muse, mutect2, varscan2
- ATG2A | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65966145; called by muse, mutect2, varscan2
- BRINP1 | c.1712A>G p.H571R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV56294856; called by muse, mutect2, varscan2
- BRINP2 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV64177556; called by muse, mutect2, varscan2
- BRINP2 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV100838226, COSV64175956; called by muse, mutect2, varscan2
- C1QTNF7 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770797389, COSV54851238; called by muse, mutect2, varscan2
- C3 | c.3938G>A p.W1313* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs112522704, COSV55570447, COSV99837003; called by mutect2, varscan2
- C6 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs965646015, COSV54707106, COSV99667477; called by muse, varscan2
- C9orf131 | c.1300A>G p.N434D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV56610103; called by muse, mutect2, varscan2
- CA6 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as rs762601224, COSV101077373, COSV66261710; called by mutect2, varscan2
- CABP5 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53152250; called by muse, mutect2, varscan2
- CACNA1I | c.4649G>A p.R1550Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1210064313, COSV100361026; called by muse, mutect2, varscan2
- CADM2 | c.964C>T p.P322S (on ENST00000407528 / NM_001167674.2; = p.P324S on NM_153184.4) | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.231); catalogued as COSV67362762; called by muse, mutect2, varscan2
- CATSPERB | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99831523; called by muse, varscan2
- CCAR2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99254717; called by muse, mutect2
- CCAR2 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99254676, COSV99254718; called by muse, mutect2
- CD163 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.115); catalogued as COSV63130159; called by muse, mutect2, varscan2
- CD1A | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99192533; called by mutect2, varscan2
- CD207 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV69651831; called by muse, mutect2, varscan2
- CDH8 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs867143514, COSV54855004, COSV54860584; called by muse, mutect2, varscan2
- CDSN | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs748961989, COSV52537538; called by mutect2, varscan2
- CES4A | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV58652275; called by muse, mutect2, varscan2
- CFHR4 | c.1624G>A p.G542R (on ENST00000367416 / NM_001201551.2; = p.G296R on NM_006684.5) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762680689, COSV52226276, COSV99259836; called by muse, mutect2, varscan2
- CHAT | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.752); catalogued as rs1468069871, COSV100340571; called by muse, mutect2, varscan2
- CNBD2 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV62586538; called by muse, mutect2, varscan2
- CNTN3 | c.1919C>T p.S640F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV55162661; called by muse, mutect2, varscan2
- CNTN4 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61869771; called by mutect2, varscan2
- CNTNAP1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV52848653; called by muse, mutect2, varscan2
- COG1 | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs747814037, COSV55428731; called by mutect2, varscan2
- COL12A1 | c.8687G>A p.G2896E | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750491475, COSV59391791; called by muse, mutect2, varscan2
- CPS1 | c.3845T>A p.V1282E | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51804973; called by muse, mutect2, varscan2
- CSNK1A1L | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV65789464; called by muse, mutect2, varscan2
- CUX2 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774991259, COSV55622878; called by mutect2, varscan2
- CXorf58 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101003045, COSV64858659; called by muse, mutect2, varscan2
- CYP2C19 | c.1080C>A p.D360E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs775381143, COSV64907171; called by muse, mutect2, varscan2
- CYP3A5 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV56118726; called by muse, mutect2, varscan2
- CYP4B1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54721958; called by muse, varscan2
- DACH1 | c.1324C>T p.P442S (on ENST00000619232 / NM_001366712.1; = p.P390S on NM_080759.6) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as rs747753827, COSV57493215; called by muse, mutect2, varscan2
- DDX60L | c.3668G>A p.R1223K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778220209, COSV52710491; called by muse, mutect2, varscan2
- DNAH10 | c.2438C>T p.S813L (on ENST00000409039; = p.S752L on NM_207437.3) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV68990008; called by muse, mutect2, varscan2
- DNAH5 | c.7063G>A p.D2355N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54208247; called by muse, varscan2
- DPP3 | c.719G>C p.R240P | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs749772984, COSV64756288; called by muse, mutect2, varscan2
- DPP4 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs147146003; called by muse, mutect2, varscan2
- DSCAM | c.5470G>A p.E1824K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68023134; called by muse, mutect2, varscan2
- DSG1 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57134024; called by muse, mutect2, varscan2
- DUOX2 | c.2978C>T p.P993L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV66531177; called by muse, mutect2, varscan2
- E2F8 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV51462368, COSV51465856; called by muse, mutect2, varscan2
- ENC1 | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs763791861, COSV56628952, COSV56629110; called by muse, varscan2
- ERCC1 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs149666093, COSV50003735; called by mutect2, varscan2
- F9 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54379311, COSV99496814; called by muse, mutect2, varscan2
- FAM117B | c.763G>C p.A255P | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100288044, COSV57417667; called by muse, mutect2
- FAM131A | c.565C>T p.L189F (on ENST00000310585; = p.L220F on NM_144635.5) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV55600083; called by muse, mutect2, varscan2
- FAM13A | c.2787A>T p.K929N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV51999151; called by muse, mutect2, varscan2
- FAM184A | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV58852628; called by muse, mutect2, varscan2
- FASLG | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60679898; called by muse, mutect2, varscan2
- FBN2 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs760247833, COSV52500003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCRL1 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as COSV63823633, COSV63824348; called by muse, mutect2, varscan2
- FCRL4 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.088); catalogued as rs772445378, COSV54860829; called by muse, mutect2, varscan2
- FCRL6 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as rs1459161329, COSV58940498; called by muse, mutect2, varscan2
- FLNC | c.2165G>A p.G722D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as COSV57952188; called by mutect2, varscan2
- FLT1 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56721678; called by muse, mutect2, varscan2
- FMN2 | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs776610158, COSV60415573; called by mutect2, varscan2
- FOLH1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV57046969; called by mutect2, varscan2
- GABRG1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs940269899, COSV54951321; called by muse, mutect2, varscan2
- GIMAP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs865805939, COSV61032437; called by muse, mutect2, varscan2
- GJB6 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766604251, CM1110301, COSV53832071; called by muse, varscan2
- GJD2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51747616; called by muse, mutect2, varscan2
- GOLGB1 | c.7292A>G p.N2431S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV61463165; called by muse, mutect2, varscan2
- GPR101 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV53237880; called by muse, mutect2, varscan2
- GPR119 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1348551327, COSV52275219; called by muse, mutect2, varscan2
- GPR176 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV54443955; called by muse, mutect2, varscan2
- GPX6 | c.360-1G>A p.X120_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as COSV62657124; called by muse, mutect2, varscan2
- GRIA2 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV52385386; called by muse, varscan2
- GRIN2B | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV74205158; called by muse, mutect2, varscan2
- GRM7 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as COSV63135106; called by mutect2, varscan2
- GUCY1A2 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs376266445; called by muse, varscan2
- GUCY2C | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474482729, COSV53788069; called by muse, mutect2, varscan2
- HAUS1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV56359776; called by muse, mutect2, varscan2
- HEATR9 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs777660364; called by muse, mutect2, varscan2
- HTR5A | c.957G>A p.W319* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV55280931; called by muse, mutect2, varscan2
- IGKV2D-29 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs375110679, COSV101534389; called by mutect2, varscan2
- IKZF3 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs762400597, COSV53100595; called by muse, mutect2, varscan2
- IL13RA2 | c.999T>G p.G333= | Splice Region (SNP) | VAF 10/18 reads (56%) | catalogued as COSV54564403; called by muse, mutect2, varscan2
- INO80 | c.4394C>T p.A1465V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV62736801; called by muse, mutect2, varscan2
- ISM2 | c.1120G>A p.E374K (on ENST00000342219 / NM_199296.3; = p.L258= on NM_182509.4) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV53634347; called by muse, mutect2, varscan2
- ITGA8 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs867515862, COSV65226391; called by muse, mutect2, varscan2
- ITGAE | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.564); catalogued as COSV53990786; called by mutect2, varscan2
- ITGBL1 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs753390115, COSV66006406; called by mutect2, varscan2
- ITIH2 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as COSV64432420; called by muse, mutect2, varscan2
- ITSN2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61944828; called by muse, mutect2, varscan2
- KCNH1 | c.2163G>A p.M721I (on ENST00000271751 / NM_172362.3; = p.M694I on NM_002238.4) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs746527925, COSV55073397; called by mutect2, varscan2
- KCNK13 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.303); catalogued as COSV56411546, COSV56413751; called by muse, mutect2, varscan2
- KCTD3 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV52065021; called by muse, varscan2
- KHDRBS2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as rs868714236, COSV55428923; called by muse, mutect2, varscan2
- KIR2DL3 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV100667974; called by mutect2, varscan2
- KLHL13 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53245841; called by muse, mutect2, varscan2
- KNG1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV53976673; called by muse, mutect2, varscan2
- KRT6A | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58104225; called by muse, mutect2, varscan2
- KRT74 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV59770804; called by muse, mutect2, varscan2
- KRTAP10-8 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs1555931244, COSV58166036; called by muse, mutect2, varscan2
- L3MBTL4 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780230270, COSV53116172; called by muse, mutect2, varscan2
- LAMC2 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs562010289, COSV51453448; called by muse, mutect2, varscan2
- LBR | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199675363, COSV55288037; called by muse, mutect2, varscan2
- LRP2 | c.3916C>G p.P1306A | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV55545719; called by muse, mutect2, varscan2
- LRP6 | c.4292C>T p.S1431F | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV53784671, COSV53786744; called by muse, mutect2, varscan2
- LRP6 | c.345A>C p.E115D | Missense Mutation (SNP) | VAF 81/304 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV54382713; called by muse, mutect2, varscan2
- LRRIQ1 | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs577819664, COSV67827478; called by muse, mutect2, varscan2
- LYZ | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs866562917, COSV54260583, COSV54261269; called by muse, mutect2, varscan2
- MAP3K5 | c.3737G>A p.G1246E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV62887821; called by muse, mutect2, varscan2
- MARCO | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59052812; called by muse, mutect2, varscan2
- MEGF10 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV57245620; called by muse, mutect2, varscan2
- MIA3 | c.2713C>T p.H905Y | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60510793; called by muse, mutect2, varscan2
- MISP | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs1411028983, COSV53119262; called by muse, mutect2, varscan2
- MLF2 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52570872; called by muse, mutect2, varscan2
- MNDA | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63740234; called by muse, mutect2, varscan2
- MOG | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs760213820, COSV65320873; called by muse, mutect2, varscan2
- MTMR14 | c.897G>A p.Q299= | Splice Region (SNP) | VAF 8/51 reads (16%) | catalogued as COSV56003928, COSV99931087; called by muse, mutect2, varscan2
- MUC16 | c.36472G>A p.D12158N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.206); catalogued as COSV67453259; called by muse, mutect2, varscan2
- MXRA5 | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs866078322, COSV54228420; called by muse, mutect2, varscan2
- MYO16 | c.2410C>T p.H804Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.098); catalogued as COSV51782750; called by muse, mutect2, varscan2
- MYOCD | c.1599G>A p.W533* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV58499691; called by muse, mutect2, varscan2
- NACA2 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 35/163 reads (21%) | catalogued as COSV71713100, COSV71713171; called by muse, mutect2, varscan2
- NCKAP1L | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53204632, COSV53211903; called by muse, mutect2, varscan2
- NEB | c.15149C>T p.A5050V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV50859558; called by muse, mutect2, varscan2
- NISCH | c.4462C>T p.R1488C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58733556; called by mutect2, varscan2
- NLRC5 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52651241; called by muse, mutect2, varscan2
- NRXN1 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58441811; called by muse, mutect2, varscan2
- OR2J3 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV101013620, COSV65848752; called by muse, mutect2, varscan2
- OR2K2 | c.996G>C p.L332F (on ENST00000374428; = p.L303F on NM_205859.2) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV57016394; called by muse, mutect2
- OR2T35 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311941069; called by mutect2, varscan2
- OR2W3 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV64456350; called by muse, mutect2, varscan2
- OR4S2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs267602971, COSV56746047; called by muse, mutect2, varscan2
- OR56A3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV61568597, COSV61568664; called by muse, mutect2, varscan2
- OR5P2 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs754458836, COSV61490124; called by muse, mutect2, varscan2
- OR8K3 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57131007; called by muse, mutect2, varscan2
- OSMR | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.212); catalogued as COSV57082375; called by muse, mutect2, varscan2
- PAH | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61014891; called by muse, mutect2, varscan2
- PCDH18 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61267069; called by muse, mutect2, varscan2
- PCLO | c.6460C>T p.Q2154* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV61622903; called by muse, mutect2, varscan2
- PCNX2 | c.4642C>T p.L1548F | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV50786740; called by muse, mutect2, varscan2
- PCNX2 | c.3470C>T p.S1157L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV50786811; called by muse, mutect2, varscan2
- PDE8B | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV53733592; called by muse, mutect2, varscan2
- PIK3C2G | c.4070C>T p.S1357L (on ENST00000676171; = p.S1316L on NM_004570.5) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1456081050, COSV56802004; called by mutect2, varscan2
- PIP5K1C | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1267600243, COSV58950876; called by muse, mutect2, varscan2
- PLEKHM1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV69598636; called by muse, mutect2, varscan2
- PLK1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs749527952, COSV55620232; called by muse, mutect2, varscan2
- PMVK | c.281A>C p.K94T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.088); catalogued as COSV63785683; called by muse, mutect2, varscan2
- POTEH | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV100625107; called by muse, varscan2
- PPP1R36 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53901291; called by muse, mutect2, varscan2
- PRKN | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV58209293; called by muse, mutect2, varscan2
- PRPF40A | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV62957067, COSV62959041; called by muse, mutect2, varscan2
- PRSS45P | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.621); catalogued as COSV70576952; called by muse, mutect2, varscan2
- PRUNE2 | c.5393T>C p.V1798A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV65038946; called by muse, mutect2, varscan2
- PTH2R | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs747468776, COSV55914670; called by muse, mutect2, varscan2
- PTPRN | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.068); catalogued as COSV55346452; called by muse, varscan2
- PTPRT | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.656); catalogued as COSV100625556, COSV61967919, COSV62000653; called by muse, mutect2, varscan2
- RFX6 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as COSV100263998; called by muse, mutect2, varscan2
- RGS22 | c.2687G>A p.R896Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs752527585, COSV62659020; called by mutect2, varscan2
- RGS7 | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58534395, COSV58548067; called by muse, mutect2, varscan2
- SALL1 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51754841; called by muse, mutect2
- SALL1 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs267604571, COSV51754853; called by muse, mutect2, varscan2
- SAMD4A | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867732128, COSV51878150; called by muse, mutect2, varscan2
- SCN11A | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs143537709, COSV56566354, COSV56579756; called by muse, mutect2, varscan2
- SCN2A | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV51839881, COSV51841292; called by mutect2, varscan2
- SCN2A | c.1925G>A p.G642E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99332679; called by muse, mutect2
- SCN9A | c.5324G>A p.S1775N (on ENST00000303354; = p.S1764N on NM_002977.3) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV57603812; called by muse, mutect2, varscan2
- SEZ6L | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs866415012, COSV50659406; called by muse, mutect2, varscan2
- SIGLEC10 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.699); catalogued as COSV59479877; called by muse, mutect2, varscan2
- SLAMF1 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV52498206, COSV99348949; called by muse, mutect2, varscan2
- SLC26A8 | c.2494A>G p.M832V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV62884994; called by muse, mutect2, varscan2
- SLCO2A1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV60484277, COSV60487125; called by muse, mutect2, varscan2
- SLCO6A1 | c.617-1G>A p.X206_splice | Splice Site (SNP) | VAF 17/80 reads (21%) | catalogued as COSV65806752; called by muse, mutect2, varscan2
- SLFN13 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.19); catalogued as COSV53192665; called by muse, mutect2, varscan2
- SPEG | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56665469; called by muse, mutect2, varscan2
- SPINK5 | c.2153G>C p.R718T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV56250449; called by muse, mutect2, varscan2
- SPTSSB | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs745729640, COSV63218911; called by mutect2, varscan2
- SRCAP | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752554947, COSV52669273; called by muse, mutect2, varscan2
- STXBP5L | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1174925778, COSV56505072; called by muse, mutect2, varscan2
- SUPT6H | c.3716T>C p.F1239S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100112612; called by muse, mutect2, varscan2
- SYCP2L | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV51649918; called by muse, mutect2, varscan2
- SYNE1 | c.386T>A p.I129N (on ENST00000367255 / NM_182961.4; = p.I136N on NM_033071.3) | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54932732; called by muse, varscan2
- SYT16 | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV70855541; called by mutect2, varscan2
- TAAR5 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV57798467, COSV57798798; called by mutect2, varscan2
- TEX45 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs763611605, COSV100861820; called by muse, mutect2, varscan2
- TLL1 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50266672; called by muse, mutect2, varscan2
- TMEM176A | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866042127, COSV50240447, COSV99134008; called by muse, mutect2, varscan2
- TNFSF13B | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV65515887; called by muse, mutect2, varscan2
- TNFSF18 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.156); catalogued as rs868136541, COSV99514073; called by mutect2, varscan2
- TREML2 | c.149T>G p.V50G | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV72439057; called by muse, mutect2, varscan2
- TRPM2 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55967400; called by muse, mutect2, varscan2
- TRPV5 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1286528317, COSV54683008; called by muse, mutect2, varscan2
- TUBA3C | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV101262840, COSV67138997; called by muse, mutect2, varscan2
- TUBAL3 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV66814064; called by muse, mutect2, varscan2
- TUBE1 | c.1230G>T p.M410I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57888961; called by muse, mutect2, varscan2
- UGT2A3 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52359310; called by muse, mutect2, varscan2
- ULK2 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV64444745; called by muse, mutect2, varscan2
- UMODL1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68555189; called by muse, mutect2, varscan2
- UNC13C | c.5347G>A p.D1783N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.205); catalogued as COSV52852393; called by mutect2, varscan2
- UNC45B | c.2766G>A p.M922I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52093355; called by mutect2, varscan2
- UQCRC2 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV51671265; called by muse, mutect2, varscan2
- UXS1 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as rs1558678439, COSV51675913; called by muse, mutect2, varscan2
- VAV3 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58378863; called by mutect2, varscan2
- VEGFA | c.332C>T p.P111L (on ENST00000523873 / NM_001171623.1; = p.P291L on NM_003376.6) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.465); catalogued as COSV57877964; called by muse, mutect2, varscan2
- WIPF2 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60272824; called by muse, mutect2, varscan2
- XIRP2 | c.3889G>A p.E1297K (on ENST00000628543; = p.E1472K on NM_152381.6) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.232); catalogued as COSV54686034; called by mutect2, varscan2
- XIRP2 | c.7172C>T p.S2391F (on ENST00000628543; = p.S2566F on NM_152381.6) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV54688522; called by muse, mutect2, varscan2
- ZFPM2 | c.1994G>A p.G665E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as COSV65872915; called by muse, mutect2, varscan2
- ZNF233 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV61933396; called by muse, mutect2, varscan2
- ZNF664 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 8/103 reads (8%) | catalogued as COSV61877410; called by muse, mutect2
- ZSWIM2 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV54574386, COSV54577693; called by muse, mutect2, varscan2
- C3 | c.3939G>A p.W1313* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- CYFIP1 | c.1211G>A p.W404* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- HYDIN | c.5743G>A p.E1915K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by mutect2, varscan2
- PRAMEF17 | c.1388G>A p.W463* | Nonsense Mutation (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.414_416delinsTT p.S139Wfs*48 | Frame Shift Del (DEL) | VAF 27/129 reads (21%) | called by pindel, varscan2*
- TRDC | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ACMSD | c.333C>T p.F111= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs759308097, COSV51606485; called by mutect2, varscan2
- ACSM5 | c.1422G>A p.V474= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV59370207; called by muse, varscan2
- ADAMTS10 | c.963C>T p.I321= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs1053681963, COSV54352899; called by muse, mutect2, varscan2
- ADAMTSL1 | c.918C>T p.F306= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV52810879, COSV52820470; called by muse, mutect2, varscan2
- ADAMTSL2 | c.192G>A p.G64= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV63203533; called by muse, mutect2, varscan2
- ADCY7 | c.2055C>T p.I685= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs890003971, COSV54265088; called by mutect2, varscan2
- APP | c.1536C>T p.F512= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1476363021, COSV60993526; called by mutect2, varscan2
- ARHGAP36 | c.1371G>A p.R457= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV52265029; called by muse, mutect2, varscan2
- BCO1 | c.441C>T p.I147= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs776764772, COSV50728539; called by muse, mutect2, varscan2
- BRDT | c.1476G>A p.R492= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV62863876; called by muse, mutect2, varscan2
- BRPF1 | c.2697G>A p.P899= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV57403828; called by muse, mutect2, varscan2
- BTNL8 | c.1179C>T p.P393= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs570090091, COSV51457580; called by muse, varscan2
- C2orf78 | c.2715C>T p.F905= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV68516377; called by mutect2, varscan2
- CA10 | c.189G>A p.G63= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV53342352; called by muse, varscan2
- CASR | c.1644C>T p.F548= (on ENST00000490131; = p.F625= on NM_000388.4) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs761716567, COSV56135487; called by muse, mutect2, varscan2
- CD163 | c.2337G>A p.G779= | Silent (SNP) | VAF 31/163 reads (19%) | catalogued as rs970048297, COSV63130598; called by muse, mutect2, varscan2
- CD1A | c.861C>T p.G287= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs189152658, COSV99192531; called by mutect2, varscan2
- CDKL5 | c.1173G>T p.G391= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV66110577; called by muse, mutect2, varscan2
- CHML | c.36T>C p.V12= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV59363072; called by muse, mutect2
- CLPX | c.615C>T p.I205= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV55643587; called by muse, mutect2, varscan2
- CNTNAP2 | c.3483G>A p.G1161= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV62149926; called by muse, mutect2, varscan2
- CRB1 | c.2757G>A p.G919= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV66329094; called by muse, mutect2, varscan2
- CYP7A1 | c.198T>A p.V66= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs779020982, COSV56962812; called by mutect2, varscan2
- DCTN4 | c.1182C>T p.F394= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1187070537, COSV69781913; called by mutect2, varscan2
- DEFB121 | c.9C>T p.L3= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV66236106; called by muse, mutect2, varscan2
- DNAH14 | c.922C>A p.R308= (on ENST00000445597; = p.R181= on NM_144989.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 54/161 reads (34%) | catalogued as rs370187831, COSV64780782; called by muse, mutect2, varscan2
- DNAJC5B | c.138C>T p.H46= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs199903991; called by muse, mutect2, varscan2
- DOCK8 | c.1056C>T p.V352= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV66633190; called by mutect2, varscan2
- DSTYK | c.909T>C p.L303= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV65685751; called by muse, mutect2, varscan2
- EIF2D | c.1317A>G p.L439= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs555979007, COSV55112668; called by muse, mutect2, varscan2
- ERCC2 | c.1407G>A p.K469= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV67262789; called by muse, mutect2, varscan2
- EYA4 | c.1440G>A p.G480= (on ENST00000531901 / NM_001301013.1; = p.G474= on NM_004100.5) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs138141986; called by mutect2, varscan2
- FAM117B | c.765A>C p.A255= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV57417680; called by muse, mutect2
- FBXO34 | c.1674C>T p.F558= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV58253828; called by muse, mutect2, varscan2
- FBXO40 | c.2088C>T p.V696= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV57522603, COSV57523820; called by muse, mutect2, varscan2
- FCGBP | c.915C>T p.L305= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- FREM2 | c.6000C>T p.I2000= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs146568641, COSV54828137; called by mutect2, varscan2
- GABRE | c.810C>T p.F270= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV64819184; called by muse, mutect2, varscan2
- GIMAP2 | c.537C>T p.I179= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs370076034; called by muse, mutect2, varscan2
- GIMAP5 | c.450C>T p.F150= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100500282; called by muse, mutect2, varscan2
- GNAI2 | c.402C>T p.D134= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as rs781916310, COSV56493121; called by muse, mutect2, varscan2
- GPRC6A | c.1905G>A p.V635= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV59952143; called by mutect2, varscan2
- GRID2 | c.2052C>T p.D684= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV56184377; called by muse, mutect2, varscan2
- GRIK5 | c.543C>T p.F181= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV53476218; called by muse, mutect2, varscan2
- GTF2IRD1 | c.750C>T p.S250= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV56084377; called by muse, varscan2
- HOXA2 | c.24G>A p.E8= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV56065591; called by muse, mutect2, varscan2
- HTR1E | c.279C>T p.F93= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs778989808, COSV59507274; called by muse, mutect2, varscan2
- IGFN1 | c.1752G>A p.K584= (on ENST00000295591 / NM_001367841.1; = p.K3041= on NM_001164586.2) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV55168394; called by muse, mutect2
- IGHV4-28 | c.57C>T p.S19= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs377356277; called by muse, mutect2, varscan2
- IKBKB | c.1020C>T p.I340= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV60596300; called by muse, mutect2, varscan2
- IL7R | c.291G>A p.K97= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV57406821, COSV57413231; called by muse, mutect2, varscan2
- INHBA | c.807G>A p.G269= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV54220264; called by muse, mutect2
- IPO5 | c.195C>T p.L65= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV55152883; called by muse, mutect2, varscan2
- KIAA1210 | c.1020G>A p.K340= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as COSV68176022, COSV68176655; called by muse, mutect2, varscan2
- KRT75 | c.480C>T p.F160= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs530407671, COSV52870856, COSV52872758; called by mutect2, varscan2
- LNX2 | c.1635C>T p.S545= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV60334784; called by muse, mutect2, varscan2
- MCHR2 | c.516G>A p.S172= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs140465249, COSV56000919; called by muse, mutect2, varscan2
- ME1 | c.186C>T p.F62= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs748274488, COSV63838212; called by muse, mutect2, varscan2
- MGAT5B | c.1008C>T p.S336= | Silent (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- MLKL | c.1200C>T p.I400= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs780422556, COSV58204485; called by mutect2, varscan2
- MUC16 | c.17520C>T p.S5840= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV67453261; called by muse, mutect2, varscan2
- MUC2 | c.3243C>T p.S1081= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- MUC6 | c.3567G>A p.E1189= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV70136904; called by muse, varscan2
- NOS1 | c.3903C>T p.T1301= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV57608781; called by muse, mutect2, varscan2
- NPAS4 | c.639C>T p.F213= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV60649429; called by muse, mutect2, varscan2
- NPC1L1 | c.1833C>T p.F611= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV56923369; called by muse, mutect2, varscan2
- NSD3 | c.429G>T p.V143= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV57617703; called by muse, mutect2, varscan2
- OR10Z1 | c.42C>T p.F14= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs557909559, COSV63524167; called by muse, mutect2, varscan2
- OR2A25 | c.210C>T p.I70= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs746269504, COSV68716976; called by mutect2, varscan2
- OR2M7 | c.36C>T p.F12= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as COSV58738314; called by muse, mutect2, varscan2
- OR4C12 | c.330C>T p.I110= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as COSV58859529; called by muse, varscan2
- OR4C12 | c.180C>T p.F60= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV58859427; called by muse, varscan2
- OR4K13 | c.216C>T p.I72= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV59859203; called by muse, mutect2, varscan2
- OR4K14 | c.348G>A p.L116= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV59292410; called by muse, mutect2, varscan2
- OR4N5 | c.882G>A p.V294= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV61320282; called by muse, mutect2, varscan2
- OR52E2 | c.42C>T p.F14= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV58612143; called by muse, mutect2, varscan2
- OR52E6 | c.690C>T p.P230= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs748767993, COSV61431590; called by mutect2, varscan2
- OR6A2 | c.615C>T p.F205= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs865944663, COSV60264638; called by muse, mutect2, varscan2
- OSBPL2 | c.309C>T p.F103= (on ENST00000313733 / NM_144498.4; = p.F91= on NM_014835.4) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV58215713; called by muse, varscan2
- OTOP3 | c.342C>T p.S114= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV60912621; called by muse, mutect2, varscan2
- PAPPA2 | c.4548C>T p.L1516= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV62793101, COSV62796021; called by muse, mutect2, varscan2
- PCLO | c.1296G>A p.K432= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV61622921; called by muse, mutect2, varscan2
- PKP2 | c.597C>T p.I199= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs866985131, COSV50727106, COSV50728255; called by mutect2, varscan2
- POT1 | c.1551C>T p.S517= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs1447234373, COSV62928705; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPFIA4 | c.1959C>T p.S653= (on ENST00000447715; = p.S654= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV55312873; called by muse, mutect2, varscan2
- PTPN13 | c.5751C>T p.S1917= (on ENST00000411767 / NM_080683.3; = p.S1898= on NM_006264.3) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs200125083, COSV100365047, COSV57403337; called by mutect2, varscan2
- PTPRK | c.4116G>A p.T1372= (on ENST00000368215 / NM_001291984.2; = p.T1373= on NM_002844.4) | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs138416879; called by muse, mutect2, varscan2
- PTPRT | c.3660C>T p.F1220= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100629633, COSV61967325, COSV61967912; called by muse, mutect2, varscan2
- RALB | c.375C>T p.V125= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs148143386; called by muse, mutect2, varscan2
- RASGRP3 | c.603C>T p.I201= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as COSV67820991; called by muse, mutect2, varscan2
- RNF31 | c.1332C>T p.A444= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV53758798; called by muse, mutect2, varscan2
- RSPH4A | c.492G>A p.R164= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs532331878, COSV57633907; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.4350C>T p.F1450= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV63671364; called by muse, mutect2, varscan2
- SELE | c.1311G>A p.P437= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs144324234; called by muse, mutect2, varscan2
- SELENOM | c.360C>T p.P120= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs751401348, COSV60776317; called by mutect2, varscan2
- SFTPB | c.636G>A p.R212= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV60892878; called by muse, mutect2, varscan2
- SGCD | c.670C>T p.L224= (on ENST00000435422 / NM_001128209.2; = p.L225= on NM_000337.5) | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV61905782; called by muse, mutect2, varscan2
- SHANK2 | c.4536C>T p.T1512= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs374724544, COSV53590009; called by muse, varscan2
- SHMT2 | c.1308C>T p.F436= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV61073468; called by muse, mutect2, varscan2
- SIGLEC11 | c.1905G>A p.G635= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs993278999, COSV101357084, COSV68567546; called by muse, mutect2
- SLC14A2 | c.543C>T p.L181= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs1405020157, COSV54907322; called by muse, mutect2, varscan2
- SLC22A25 | c.708G>A p.L236= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs759594949, COSV60594949; called by mutect2, varscan2
- SLC5A7 | c.1386C>T p.Y462= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs374527469; called by muse, varscan2
- SSH1 | c.711C>T p.S237= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV58455119; called by muse, mutect2, varscan2
- STAB2 | c.3687C>T p.F1229= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV66334152; called by muse, mutect2, varscan2
- SULT1A2 | c.90C>T p.P30= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1475032787, COSV57681136; called by muse, mutect2, varscan2
- SUPT6H | c.3717C>T p.F1239= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100112613; called by muse, mutect2, varscan2
- SYT12 | c.606C>T p.I202= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1261839420, COSV67353565; called by mutect2, varscan2
- TESPA1 | c.198G>A p.Q66= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV57257812; called by muse, mutect2, varscan2
- TEX45 | c.888G>A p.R296= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs760138380, COSV100861819; called by muse, mutect2, varscan2
- TF | c.2085C>T p.F695= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV53918538; called by muse, mutect2, varscan2
- TLR5 | c.870G>A p.V290= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV60558147; called by mutect2, varscan2
- TMEM176A | c.186C>T p.I62= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs757325954, COSV50240241; called by mutect2, varscan2
- TPK1 | c.552C>T p.G184= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV63638678; called by muse, mutect2, varscan2
- TTN | c.2718C>T p.I906= (on ENST00000591111; = p.I860= on NM_003319.4) | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV59942089; called by muse, varscan2
- UBASH3A | c.1524A>G p.E508= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV52311135; called by muse, mutect2, varscan2
- UBQLN3 | c.1038C>T p.L346= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV61163586; called by muse, mutect2, varscan2
- VPS39 | c.2535C>T p.I845= (on ENST00000348544 / NM_001301138.2; = p.I834= on NM_015289.5) | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as COSV58788472; called by muse, mutect2, varscan2
- ZBED9 | c.1503C>T p.F501= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV71729239; called by muse, mutect2, varscan2
- ZFP36L1 | c.228C>T p.A76= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs752733615, COSV60544745; called by muse, mutect2, varscan2
- ZHX2 | c.1665C>T p.T555= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV58711235; called by muse, mutect2, varscan2
- NXF5 | n.1470G>A | RNA (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99534527; called by muse, mutect2, varscan2
- TCF3 | c.1823-441T>C | Intron (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99514341; called by muse, mutect2, varscan2
- TTN | c.10360+3514G>A | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as rs868174581, COSV100622006; called by mutect2, varscan2
